Somatic mutation profile of tumor specimen TARGET-10-PAPAMS-09A (aliquot TARGET-10-PAPAMS-09A-01D) from TARGET case TARGET-10-PAPAMS, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.5 years (1,280 days).
Specimen TARGET-10-PAPAMS-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3dca43f2-ca2e-4199-8dd5-bba804481080.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPAMS-14A (Bone Marrow Normal), aliquot TARGET-10-PAPAMS-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/855db904-42ba-4a31-8b69-feb8579df97c

The open-access MAF lists 19 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 3, Nonsense Mutation 1, Frame Shift Del 1, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSM4 | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.325); catalogued as rs370415520; called by mutect2, varscan2
- ARHGAP32 | c.2506G>T p.A836S (on ENST00000310343 / NM_001378025.1; = p.A487S on NM_014715.4) | Missense Mutation (SNP) | VAF 6/109 reads (6%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV100086960; called by muse, mutect2
- CSMD3 | c.1085G>T p.R362M | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.054); catalogued as COSV99033609; called by muse, mutect2, varscan2
- LAMC3 | c.907C>T p.R303C | Missense Mutation (SNP) | VAF 30/145 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as rs376297941; called by muse, mutect2, varscan2
- PAPPA | c.3691G>T p.D1231Y | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as COSV60293176; called by muse, mutect2
- SHC4 | c.1315C>A p.P439T | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV100194176; called by muse, mutect2, varscan2
- C2CD5 | c.1513G>T p.A505S | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.039); called by muse, mutect2
- CALCRL | c.934A>T p.I312F | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- COL5A2 | c.1414G>T p.V472F | Missense Mutation (SNP) | VAF 14/270 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2
- CSNK1A1 | c.607G>T p.D203Y | Missense Mutation (SNP) | VAF 5/92 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- MAPRE3 | c.68G>A p.W23* | Nonsense Mutation (SNP) | VAF 18/101 reads (18%) | called by muse, mutect2, varscan2
- OTC | c.772A>T p.N258Y | Missense Mutation (SNP) | VAF 36/274 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SAE1 | c.948G>T p.K316N | Missense Mutation (SNP) | VAF 8/131 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2
- SETD2 | c.7023del p.Q2342Kfs*11 | Frame Shift Del (DEL) | VAF 21/113 reads (19%) | called by mutect2, pindel, varscan2
- TOP2A | c.3721-1G>T p.X1241_splice | Splice Site (SNP) | VAF 7/79 reads (9%) | called by muse, mutect2
- CSMD3 | c.1084A>C p.R362= | Silent (SNP) | VAF 13/86 reads (15%) | called by muse, mutect2, varscan2
- SLCO1B1 | c.1212C>T p.T404= | Silent (SNP) | VAF 29/78 reads (37%) | catalogued as rs537508858; called by muse, mutect2, varscan2
- TCEAL5 | c.372G>A p.T124= | Silent (SNP) | VAF 9/139 reads (6%) | catalogued as rs759900448, COSV65502679; called by muse, mutect2
- TTC19 | c.*1255C>T | 3'UTR (SNP) | VAF 38/72 reads (53%) | called by muse, mutect2, varscan2
